CCDI case PBCGZA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/8e80e55a-666a-4b1a-a906-26326fc91bc4

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: External ear; Age at diagnosis: 18.1 years (6,627 days).

Biospecimens (3 samples)
- Sample 0DRQSR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRQT3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRQTC: Tissue type: Tumor; Specimen type: Solid Tissue.
